Somatic mutation profile of tumor specimen TCGA-06-6693-01A (aliquot TCGA-06-6693-01A-11D-1845-08) from TCGA case TCGA-06-6693, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.6 years (23,585 days).
Specimen TCGA-06-6693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d40780f4-e1bd-46a5-ba6d-785d608db001.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6693-10A (Blood Derived Normal), aliquot TCGA-06-6693-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b376b8c8-e62a-48e6-b943-090e3610c14a

The open-access MAF lists 56 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 5, Frame Shift Del 2, Intron 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.5011C>T p.R1671* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | catalogued as COSV65067698; called by muse, mutect2, varscan2
- ANO9 | c.1790C>A p.T597N | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60382355; called by muse, mutect2, varscan2
- ARHGEF11 | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as COSV59352377; called by muse, mutect2, varscan2
- BAHD1 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs143744499; called by muse, mutect2, varscan2
- BNC2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0.066); catalogued as rs1191107098, COSV66140604; called by muse, mutect2, varscan2
- CLEC14A | c.1135A>T p.K379* | Nonsense Mutation (SNP) | VAF 37/71 reads (52%) | catalogued as COSV60561655; called by muse, mutect2, varscan2
- CRLF3 | c.860G>C p.S287T | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60835190; called by muse, mutect2, varscan2
- CSH2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201103017; called by muse, mutect2, varscan2
- DIP2C | c.3064G>A p.G1022S | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV55145622; called by muse, mutect2, varscan2
- EPHA1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51968479; called by muse, mutect2, varscan2
- FRAS1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 55/64 reads (86%) | catalogued as rs775259788, COSV53588639; called by muse, mutect2, varscan2
- GPR82 | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV56886626; called by muse, mutect2, varscan2
- HLA-DRB1 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs17433947; called by muse, mutect2
- HPGD | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.897); catalogued as COSV56661585; called by muse, mutect2, varscan2
- LRRK1 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs939724696, COSV52601592, COSV52606441; called by muse, mutect2, varscan2
- MACC1 | c.2479G>T p.E827* | Nonsense Mutation (SNP) | VAF 68/137 reads (50%) | catalogued as rs776961275, COSV60540760; called by muse, mutect2, varscan2
- MAGEB16 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.07); catalogued as COSV67873543, COSV67874256; called by muse, varscan2
- MAGIX | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs782556687, COSV66255666; called by muse, mutect2, varscan2
- NIBAN3 | c.1333A>G p.S445G | Missense Mutation (SNP) | VAF 118/294 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV56305304; called by muse, mutect2, varscan2
- NIN | c.1897-1G>C p.X633_splice | Splice Site (SNP) | VAF 23/56 reads (41%) | catalogued as COSV55379969; called by muse, mutect2, varscan2
- NOL8 | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.02); catalogued as COSV62634065; called by muse, mutect2, varscan2
- OBSCN | c.11801G>A p.R3934H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs371734358, COSV52739016; called by muse, mutect2, varscan2
- OR52E4 | c.793T>A p.F265I | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57623779; called by muse, mutect2, varscan2
- OR6M1 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as rs150135307; called by muse, mutect2, varscan2
- PACS1 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as rs1270980890, COSV57696088; called by muse, mutect2, varscan2
- PLCXD3 | c.391T>C p.F131L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV60604506; called by muse, mutect2, varscan2
- PLTP | c.1244A>G p.K415R | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV51940585; called by muse, mutect2, varscan2
- RSPO3 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1461030071, COSV63149426; called by muse, mutect2, varscan2
- SH3RF3 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs765272189, COSV58680212; called by muse, mutect2, varscan2
- SIX4 | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.883); catalogued as COSV53668517; called by muse, mutect2, varscan2
- SRL | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs759301381, COSV68422802; called by muse, mutect2, varscan2
- THSD4 | c.1925T>C p.F642S | Missense Mutation (SNP) | VAF 215/489 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55960926; called by muse, mutect2, varscan2
- TMC2 | c.2324T>A p.L775Q | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62649685; called by muse, mutect2, varscan2
- TRPM2 | c.1938G>C p.Q646H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV55965752; called by muse, mutect2
- ZBTB2 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57311594; called by muse, mutect2, varscan2
- ZNF180 | c.1337T>G p.F446C | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55419560, COSV99659992; called by muse, mutect2
- ZNF208 | c.2780G>A p.S927N | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV68100354; called by muse, mutect2, varscan2
- DNAH2 | c.1545del p.Y516Tfs*11 | Frame Shift Del (DEL) | VAF 69/190 reads (36%) | called by mutect2, pindel, varscan2
- GAGE2E | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 70/2198 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PDE4A | c.694del p.R232Gfs*35 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- ARAP2 | c.4482G>A p.V1494= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV58282450; called by muse, mutect2, varscan2
- CEP126 | c.405A>G p.K135= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV54821493; called by muse, mutect2
- CHRNA10 | c.786C>T p.A262= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs1461950576, COSV51702847; called by muse, mutect2, varscan2
- CLEC14A | c.579C>T p.R193= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs779422328, COSV60561665; called by muse, mutect2, varscan2
- ECPAS | c.3783G>A p.V1261= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV52191447; called by muse, mutect2, varscan2
- GALNS | c.1176G>A p.A392= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs398123431, COSV51935613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCAR2 | c.825G>A p.A275= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs202067823, COSV61024215; called by muse, mutect2, varscan2
- OR5L1 | c.840C>T p.V280= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as rs764498675, COSV61732735, COSV61734454; called by muse, mutect2, varscan2
- PHEX | c.1188C>G p.T396= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs1177960104, COSV65073700; called by muse, mutect2, varscan2
- PPP1R12A | c.2115A>G p.Q705= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1320375856, COSV54105300; called by muse, mutect2, varscan2
- PROS1 | c.228G>A p.P76= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs6121, COSV62397595; called by muse, mutect2, varscan2
- VPS13C | c.1065G>A p.A355= (on ENST00000644861 / NM_020821.3; = p.A312= on NM_017684.5) | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs767109326, COSV51121152; called by muse, mutect2, varscan2
- ZGPAT | c.1470G>A p.A490= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs571008731, COSV56648560; called by muse, mutect2
- AIRE | c.880-155G>C | Intron (SNP) | VAF 24/144 reads (17%) | catalogued as COSV99381270; called by muse, mutect2, varscan2
- ARHGAP6 | c.1908-4409C>T | Intron (SNP) | VAF 24/46 reads (52%) | catalogued as rs765781400, COSV100272663; called by muse, mutect2, varscan2
- FAM74A3 | n.365G>A | RNA (SNP) | VAF 27/98 reads (28%) | catalogued as rs1275849448; called by muse, mutect2, varscan2
